Somatic mutation profile of tumor specimen TCGA-AG-3890-01A (aliquot TCGA-AG-3890-01A-01W-1073-09) from TCGA case TCGA-AG-3890, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.8 years (22,950 days).
Specimen TCGA-AG-3890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9a856b6-3768-4849-a4ad-256ddb9a5695.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3890-10A (Blood Derived Normal), aliquot TCGA-AG-3890-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b603d56d-a338-4bad-8615-81b93378e42a

The open-access MAF lists 104 somatic variants for this specimen: 79 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 22, Frame Shift Ins 3, 3'Flank 1, Frame Shift Del 1, RNA 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100053399, COSV51014574; called by muse, mutect2, varscan2
- ABCA13 | c.7838A>C p.D2613A | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV71284685, COSV71291603; called by muse, mutect2
- APC | c.2803del p.Y935Tfs*20 | Frame Shift Del (DEL) | VAF 49/103 reads (48%) | catalogued as CD041147, CD971993; called by mutect2, pindel, varscan2
- ASH1L | c.6960C>A p.H2320Q (on ENST00000368346 / NM_001366177.2; = p.H2315Q on NM_018489.3) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64210968; called by muse, mutect2, varscan2
- ASXL3 | c.3971T>A p.L1324Q | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.368); catalogued as COSV52473122; called by muse, mutect2, varscan2
- BCL9 | c.2726dup p.V910Cfs*42 | Frame Shift Ins (INS) | VAF 43/156 reads (28%) | catalogued as rs1553205212; called by mutect2, varscan2
- BEX3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55421543; called by muse, mutect2
- BRDT | c.2635A>G p.K879E | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100746417; called by muse, mutect2
- CASZ1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775345608, COSV59738714; called by muse, mutect2, varscan2
- CD1E | c.1058A>C p.N353T | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV63772051; called by muse, mutect2, varscan2
- CDYL | c.1168G>T p.V390L (on ENST00000328908 / NM_001368125.1; = p.V336L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.573); catalogued as COSV59360795; called by muse, mutect2, varscan2
- CFAP47 | c.4498G>A p.D1500N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs866595417, COSV57975350; called by muse, mutect2, varscan2
- CHML | c.992T>A p.L331Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59364453, COSV59366012; called by muse, mutect2, varscan2
- CNTN1 | c.1306T>A p.C436S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61642745; called by muse, mutect2, varscan2
- COL12A1 | c.8350C>T p.P2784S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.86); catalogued as COSV59401579; called by muse, mutect2, varscan2
- CRACR2A | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV52915991; called by muse, mutect2
- CYP4Z1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1311229506, COSV61965945; called by muse, mutect2, varscan2
- DIAPH3 | c.2678A>T p.K893M (on ENST00000400324 / NM_001042517.2; = p.K630M on NM_030932.3) | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV57375347; called by muse, mutect2, varscan2
- DIS3 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1297002186, COSV66707331; called by muse, mutect2, varscan2
- ENPP4 | c.946T>A p.L316M | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100320345; called by muse, mutect2
- EPHA4 | c.2672C>T p.T891I | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.206); catalogued as COSV56039004; called by muse, mutect2, varscan2
- FERD3L | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV51763535; called by muse, mutect2, varscan2
- FSHR | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437324; called by muse, mutect2
- GPR19 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.068); catalogued as COSV60124177; called by muse, mutect2, varscan2
- GTF2H1 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56379335; called by muse, mutect2
- HMMR | c.1516C>G p.Q506E | Missense Mutation (SNP) | VAF 163/223 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV62375061; called by muse, mutect2, varscan2
- IGLV3-21 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs537715817; called by muse, mutect2, varscan2
- INTS6L | c.2260G>C p.D754H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV100878260, COSV66085283; called by muse, mutect2, varscan2
- ITPR1 | c.1424A>G p.K475R (on ENST00000354582; = p.K460R on NM_002222.7) | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100231585; called by muse, mutect2
- KCNB2 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 129/292 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.058); catalogued as COSV73051602; called by muse, mutect2, varscan2
- KIFC3 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.279); catalogued as COSV65551948; called by muse, mutect2, varscan2
- L1CAM | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs782070899, COSV62828384; called by muse, mutect2
- LCMT1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs971810471, COSV66726160; called by muse, mutect2, varscan2
- LRRC49 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/207 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV51436879; called by muse, mutect2, varscan2
- LZTS1 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV56117680; called by muse, mutect2, varscan2
- MBD5 | c.3755G>T p.R1252I | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1484563360, COSV68696274; called by muse, mutect2, varscan2
- MCF2 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58490363; called by muse, mutect2, varscan2
- MCM10 | c.2602G>A p.A868T (on ENST00000484800 / NM_182751.3; = p.A867T on NM_018518.5) | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.66); catalogued as COSV66335672; called by muse, mutect2, varscan2
- MERTK | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 98/143 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54932706; called by muse, mutect2, varscan2
- MUC16 | c.5905C>A p.P1969T | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67467534; called by muse, mutect2, varscan2
- MYH2 | c.1025T>C p.L342S | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99820300; called by muse, mutect2
- NDST3 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV56624662; called by muse, mutect2, varscan2
- NLRP7 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs886842686, COSV60177989; called by muse, mutect2, varscan2
- NUP210L | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs944939030, COSV55152764; called by muse, mutect2, varscan2
- OLIG3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62988569; called by muse, mutect2, varscan2
- OR10A3 | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62459853; called by muse, mutect2, varscan2
- OR10Z1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 192/501 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63525735; called by muse, mutect2, varscan2
- PCYT1A | c.109T>G p.C37G | Missense Mutation (SNP) | VAF 107/591 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53058901; called by muse, mutect2, varscan2
- PDYN | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 110/455 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54102256, COSV54102710; called by muse, mutect2, varscan2
- PHF3 | c.4601C>T p.T1534I | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100013430; called by muse, mutect2
- PPP1CB | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV56091406; called by muse, mutect2, varscan2
- PTCHD4 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV59791292; called by muse, mutect2, varscan2
- RNASE3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371809756, COSV58959378; called by muse, mutect2
- RYR3 | c.3308G>C p.W1103S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212918; called by muse, varscan2
- SAMD9 | c.4312T>G p.L1438V | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101180278; called by muse, mutect2
- SEMA6C | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59005560; called by muse, mutect2
- SHMT1 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57399807; called by muse, mutect2, varscan2
- SLC6A14 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903144; called by muse, mutect2
- SLCO1A2 | c.1857C>G p.I619M | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100261530, COSV56606752; called by muse, mutect2, varscan2
- SMG7 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs749345886, COSV61632907; called by muse, mutect2, varscan2
- SREK1IP1 | c.242G>C p.S81T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.483); catalogued as COSV101536176, COSV72486346; called by muse, mutect2, varscan2
- STAC | c.179T>G p.F60C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56214976; called by muse, mutect2, varscan2
- STIL | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV54547465, COSV54552051; called by muse, mutect2, varscan2
- STXBP4 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 40/717 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100178193; called by muse, mutect2
- TP53 | c.1003_1004insA p.R335Qfs*2 | Frame Shift Ins (INS) | VAF 51/87 reads (59%) | catalogued as COSV53329054; called by mutect2, pindel, varscan2
- TSPYL5 | c.1127A>T p.N376I | Missense Mutation (SNP) | VAF 137/459 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59072147; called by muse, mutect2, varscan2
- ZFP28 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs767308660, COSV56737043; called by muse, mutect2, varscan2
- ZNF138 | c.451T>C p.F151L (on ENST00000307355 / NM_001367572.1; = p.F125L on NM_006524.4) | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV56466533; called by muse, mutect2, varscan2
- ZNF451 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV62598726; called by muse, mutect2
- ZNF471 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57289971; called by muse, mutect2
- ZNF474 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs752457587, COSV56945249, COSV56946891; called by muse, mutect2, varscan2
- ZNF638 | c.1586T>G p.F529C | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV100039030; called by muse, mutect2
- ZNF705A | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV63733491; called by muse, mutect2, varscan2
- ZNF830 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58490517; called by muse, mutect2, varscan2
- ZW10 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs745380788, COSV52318151; called by muse, mutect2, varscan2
- OR4F4 | c.768dup p.I257Hfs*6 | Frame Shift Ins (INS) | VAF 26/140 reads (19%) | called by mutect2, varscan2
- PCDHB9 | c.1363T>A p.S455T | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SPATA31A3 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 101/635 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TRGV9 | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKMY1 | c.1335G>C p.V445= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV56037802; called by muse, mutect2, varscan2
- CDYL | c.1167G>T p.L389= (on ENST00000328908 / NM_001368125.1; = p.L335= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV59360781; called by muse, mutect2, varscan2
- CENPE | c.4398A>G p.K1466= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as COSV54385205; called by muse, mutect2, varscan2
- COL12A1 | c.3747A>G p.T1249= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as COSV100486092; called by muse, mutect2
- FARP1 | c.339T>G p.V113= | Silent (SNP) | VAF 35/270 reads (13%) | catalogued as COSV60342727; called by muse, mutect2, varscan2
- GPNMB | c.822C>G p.L274= | Silent (SNP) | VAF 88/346 reads (25%) | catalogued as COSV51699643; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1461C>T p.H487= | Silent (SNP) | VAF 26/299 reads (9%) | catalogued as rs587605665; called by muse, mutect2, varscan2
- KIR2DL1 | c.924C>T p.C308= | Silent (SNP) | VAF 204/761 reads (27%) | catalogued as rs2916014, COSV52412738; called by muse, mutect2, varscan2
- LGR6 | c.1989C>T p.A663= (on ENST00000367278 / NM_001017403.1; = p.A611= on NM_021636.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs758170595, COSV55162044; called by muse, mutect2
- LYST | c.7017C>T p.L2339= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs201154390, COSV67707602; called by muse, mutect2, varscan2
- MCMBP | c.1539A>G p.S513= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV63509979; called by muse, mutect2, varscan2
- NABP1 | c.63A>G p.L21= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV57139117; called by muse, mutect2, varscan2
- NUTM1 | c.1734C>G p.P578= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV59217958; called by muse, mutect2, varscan2
- PCDH15 | c.5100T>C p.L1700= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as COSV57354945; called by muse, mutect2, varscan2
- PLEKHG1 | c.2904C>A p.A968= | Silent (SNP) | VAF 77/260 reads (30%) | catalogued as COSV62049342; called by muse, mutect2, varscan2
- PLIN2 | c.102C>G p.L34= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV52802674, COSV52803920; called by muse, mutect2, varscan2
- SLC6A15 | c.115C>T p.L39= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as COSV57025600, COSV99880943; called by muse, mutect2
- SPATA31A1 | c.1356T>C p.N452= | Silent (SNP) | VAF 22/652 reads (3%) | called by muse, mutect2
- TADA2B | c.633G>A p.R211= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV53827678; called by muse, mutect2
- TET2 | c.1572G>A p.E524= | Silent (SNP) | VAF 37/313 reads (12%) | catalogued as rs1471734269, COSV54423063; called by muse, mutect2, varscan2
- TG | c.7599C>T p.T2533= | Silent (SNP) | VAF 26/227 reads (11%) | catalogued as COSV99601266; called by muse, mutect2, varscan2
- TPH2 | c.1398G>A p.V466= | Silent (SNP) | VAF 6/182 reads (3%) | catalogued as COSV100422126; called by muse, mutect2
- AC073310.1 | n.1011C>T | RNA (SNP) | VAF 72/250 reads (29%) | called by muse, mutect2, varscan2
- PREX2 | c.2716-2890A>C | Intron (SNP) | VAF 34/113 reads (30%) | catalogued as COSV55787052; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100266 C>T | 3'Flank (SNP) | VAF 5/25 reads (20%) | catalogued as rs1220612336; called by muse, mutect2
